Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A2LD, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A2LD-01A (Primary Tumor).

**FINAL DIAGNOSIS:**

PART 1: URETER, LEFT DISTAL, BIOPSY -

- A. SEGMENT OF URETER LINED BY BENIGN UROTHELIAL MUCOSA.
- B. NO UROTHELIAL CARCINOMA IN SITU (CIS) NOR INVASIVE UROTHELIAL CARCINOMA IS SEEN.

PART 2: URETER, LEFT DISTAL, BIOPSY -

- A. SEGMENT OF URETER LINED BY REACTIVE UROTHELIUM.
- B. NO UROTHELIAL CARCINOMA IN SITU (CIS) NOR INVASIVE UROTHELIAL CARCINOMA IS SEEN.

PART 3: URINARY BLADDER, CYSTECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED UROTHELIAL CARCINOMA (3.2 CM), HIGH GRADE (WHO / ISUP), WITH BIZARRE PLEOMORPHIC GIANT CELLS.
- B. THE CARCINOMA INVADERS THE DETRUSOR MUSCLE AND EXTENDS INTO THE ADIPOSE TISSUE.
- C. SURGICAL MARGINS ARE FREE OF TUMOR.
- D. FLAT CARCINOMA IN SITU IS IDENTIFIED.
- E. NO PERINEURAL INVASION IS IDENTIFIED.
- F. ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. PATHOLOGIC STAGE = pT3a N1 MX.
- H. CYSTITIS CYSTICA AND SQUAMOUS METAPLASIA IDENTIFIED.

PART 4: LYMPH NODE, LEFT PELVIC, EXCISION -

METASTATIC CARCINOMA INVOLVING ONE OF FIVE LYMPH NODES (1/5).

PART 5: LYMPH NODE, RIGHT PELVIC, EXCISION -

NO CARCINOMA IDENTIFIED IN ELEVEN LYMPH NODES (0/11).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY URINARY BLADDER TUMORS

SPECIMEN TYPE:

TUMOR SITE:

TUMOR SIZE:

HISTOLOGIC TYPE:

ASSOCIATED EPITHELIAL LESIONS:

HISTOLOGIC GRADE:

TUMOR CONFIGURATION:

PATHOLOGIC STAGING (pTNM):

Radical cystectomy

Trigone, Other: Left and right uretero-ostia

Greatest dimension: 3.2 cm

Urothelial (transitional cell) carcinoma

Cannot be determined

Urothelial carcinoma - High-grade

Solid/nodule, Flat

pT3a

pN1

Number of nodes examined: 16

Number of nodes involved: 1

pMX

Margins uninvolved by invasive carcinoma

Present

MARGINS:

VENOUS/LYMPHATIC (LARGE/SMALL) VESSEL INVASION (V/L):

DIRECT EXTENSION OF INVASIVE TUMOR: Perivesical fat

ADDITIONAL PATHOLOGIC FINDINGS: Urothelial carcinoma in situ

ICD-0-3

Carcinoma, urothelial, NOS 8120/3

Path Site: bladder, NOS C67.9

CQCF bladder, trigone C67.0

fw 8/19/11

Source: NCI Genomic Data Commons file 1a810fec-acc4-4208-9c5a-b4979754321a (TCGA-BT-A2LD.69B3EA67-CD1F-4B86-989C-DEE4FEFA7906.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).